CCDI case PBBVDK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/ecb4c1ec-6863-42b3-a087-43865f8deba3

Demographics
Sex at birth: female.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,303 days).

Biospecimens (3 samples)
- Sample 0DI5EF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI5EV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI5FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
